Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JB, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JB-01A (Primary Tumor).

[page 1 of 2]
Requesting Doctor's Information:

ICD-O-3

Carcinoma, adrenal cortical 8370/3

Site: Adrenal Gland, cortex C74.0

9/20/13

SPECIMEN TYPE: Adrenal

CLINICAL NOTES:

Right adrenal. yo male, few months H/O fevers, weight loss. R) adrenal mass on CT -> malignant cells on FNAB ?type. NOT lymphoma of melanoma. B/H hep C+ve. Rheumatic heart disease. ?primary adrenal tumour. ?metastasis.

MACROSCOPIC:

"Right adrenal gland". The specimen consists of adrenal gland and surrounding adipose tissue which is haemorrhagic in nature. The specimen measures 80 x 65 x 60mm and weighs approximately 125g. The surrounding adipose tissue is markedly congested and haemorrhagic. On sectioning, at least 70 to 80% of the adrenal gland has been replaced by tumour. It has a heterogeneous appearance with solid white areas, fibrous bands, and a large area of haemorrhage. In a few areas, the tumour appears to be abutting the resection margin.

Blocks 1 to 4 - contain a representative section through the adrenal and adrenal mass, the slice has been sectioned into four pieces

Blocks 5 to 7 - contain representative tissue of tumour in areas where it appears to abut the surrounding resection margins (blocks 6 and 7 contains areas of haemorrhage)

(A small amount of tissue has been taken for EM).

MICROSCOPIC:

Sections show adrenal tissue which has been largely replaced by a neoplastic infiltrate consisting of solid sheets of highly pleomorphic cells, most of which contain abundant eosinophilic cytoplasm. The nuclei are enlarged, vesicular and have prominent nucleoli. Mitotic figures are numerous and include a conspicuous number of atypical forms. The tumour has an infiltrative border and is seen invading both residual, cortical and medullary tissue. No penetration of the adrenal capsule is however evident. Many areas of necrosis and haemorrhage are present. No vascular space permeation is seen.

The following immunohistochemical stains were performed:

S100: Occasional scattered cells staining positive, possibly representing origin from the residual adrenal medulla.

Chromogranin: Tumour cells negative. Positive staining of residual cells of medullary origin.

HMB45: Negative.

CK7: Negative.

CK20: Negative.

Cam5.2: Occasional scattered cells with pleomorphic characteristics show weak positive staining.

HISTOPATHOLOGY

ANATOMICAL PATHOLOGY

[page 2 of 2]
Requesting Doctor's Information:

SPECIMEN TYPE: Adrenal

Vimentin: Positive.

EMA: some apparent positivity.

CEA: Negative.

AFP: Negative.

SMA: Negative.

Electron microscopy was performed at
as follows:

Report

"Whilst there are features suggestive of an adrenal cortical carcinoma, the
standard of preservation is too poor for firm diagnosis.

Pleomorphic tumour cells are in close apposition with their neighbours and,
where plasma membranes are preserved, lack intercellular junctions. Patches of
cytoplasm in some cells are occupied by what is probably altered smooth
surfaced endoplasmic reticulum. However, although mitochondria are frequently
numerous, they are too autolysed to determine whether the tubular or
tubulovesicular cristae typical of adrenal cortical cells and their tumours are
present. Rough surfaced endoplasmic reticulum tends to occur in long strands,
rather than in the short stacked cisternae, that characterises adrenal cortical
cells. Lipid droplets, though present, are not particularly numerous.

There are no features (such as melanosomes, secretory granules, tonofibrils,
lumen formation or microvilli) that would suggest metastatic tumour".

Reported by:

COMMENT: The overall appearances/findings are considered most consistent with
those of a primary adrenal cortical carcinoma.

REPORTING PATHOLOGIST:

(Electronic Signature)

Criteria	W 12/22/12	Yes	No
Case is (circled):	QUALIFIED		

Source: NCI Genomic Data Commons file 0a7a6ddf-aba9-438b-a830-deb3cca9303b (TCGA-OR-A5JB.81022A25-6D64-419D-9B97-22348E17ECEA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).